Gene-level copy-number profile of tumor specimen TCGA-04-1361-01A from TCGA case TCGA-04-1361, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 57.1 years (20,860 days).
Specimen TCGA-04-1361-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.49aff11e-7532-4ca6-9192-b6d8e8b806c1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-04-1361-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/059e8e97-4bc7-4a26-83f6-9b1ed656283e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 118; copy number 1: 16,047; copy number 2: 34,394; copy number 3: 6,213; copy number 4: 1,912; copy number 5: 711; copy number 6: 411.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-04-1361-01A-01D-0452-01): tumor purity 0.69, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 118 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:186,266,189–190,092,279, 74 genes (within-gene range 0–2) (broad region; genes not listed).
- chr12:15,911,302–19,720,801, 44 genes (within-gene range 0–1): DERA, EGLN3P1, SLC15A5, MGST1, SUPT16HP1, AC007528.1, AC007552.1, LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 940 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:30,013,952–30,834,864, 12 genes, copy number 5: LINC01648, AL137076.1, AL021921.1, AL161638.2, AL161638.1, MATN1, MATN1-AS1, AL137857.1, LAPTM5, MIR4420, AL137027.1, LINC01778.
- chr8:94,641,074–94,707,466, 1 gene, copy number 5 (within-gene range 2–5): ESRP1.
- chr8:94,688,228–145,066,685, 806 genes, copy number 5–6 (broad region; genes not listed).
- chr11:77,878,720–77,994,671, 1 gene, copy number 5 (within-gene range 4–5): INTS4.
- chr11:78,015,715–85,627,922, 84 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr11:99,020,949–100,358,885, 1 gene, copy number 6 (within-gene range 4–6): CNTN5.
- chr11:100,336,856–100,687,955, 4 genes, copy number 6: RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1.
- chr18:3,066,807–5,004,537, 31 genes, copy number 5 (within-gene range 3–5): MYOM1, RNU7-25P, AP005329.2, AP005329.3, MYL12A, AP005329.1, MYL12B, AP001025.1, LINC01895, RPL31P59, IGLJCOR18, RPL21P127, TGIF1, BOD1P1, GAPLINC, DLGAP1, RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1, AP002478.2, DLGAP1-AS3, MIR6718, RNU6-831P, DLGAP1-AS4, GAPDHP66, DLGAP1-AS5, AP005208.1, ELOCP27, AP005203.1.

Autosomal genes at a single copy (total copy number 1): 16,047. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
